HCMI case HCM-BROD-0050-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Blood Vessel Tumors; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a35ed933-bca3-4fb3-8262-ab1405cdbdbf

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1989; Vital status: Dead; Days to death: 1,486 days (4.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Primary of the connective, subcutaneous and other soft tissues (histology not recorded by GDC) (the primary disease). ICD-O-3 morphology code: 9137/3; ICD-10 code: C49.9; Age at diagnosis: 22.4 years (8,196 days); Tumor grade: GX; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/6; ICD-10 code: C79.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 24.1 years (8,819 days); Days to diagnosis: 623 days (1.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Cisplatin + Doxorubicin Hydrochloride + Gemcitabine Hydrochloride + Ifosfamide; Treatment intent type: Maintenance Therapy; Days to treatment start: 30 days; Days to treatment end: 822 days (2.3 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 1,486 days (4.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- IDH2 (Targeted Sequencing): Positive; Amino-acid change: I153V.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 57 kg; Height: 170 cm; BMI: 19.7.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0050-C49-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
- Sample HCM-BROD-0050-C49-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen.
